TCGA case TCGA-DD-AAED — Liver Hepatocellular Carcinoma (TCGA-LIHC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Liver and intrahepatic bile ducts; Tissue source site: Mayo Clinic - Rochester. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/527d2bc3-7fdd-4b08-839d-67e2f246db04

Demographics
Sex at birth: male; Race: asian; Ethnicity: not hispanic or latino; Country of residence at enrollment: South Korea; Age at index: 51 years; Vital status: Alive.

Diagnoses (2)
1. Hepatocellular carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8170/3; ICD-10 code: C22.0; Tissue or organ of origin: Liver; Site of resection or biopsy: Liver; Classification of tumor: primary; Age at diagnosis: 51.3 years (18,722 days); Year of diagnosis: 2012; AJCC staging edition: 7th; AJCC pathologic T: T1; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Child pugh classification: A; Ishak fibrosis score: 1,2 - Portal Fibrosis.
   Pathology details: Additional pathology findings: Inflammation; Consistent pathology review: Yes; Vascular invasion present: No.
   Treatment given: Treatment type: Chemoembolization; Therapeutic agents: Doxorubicin Hydrochloride; Days to treatment start: 215 days; Embolic agent: Gelfoam.
   Treatment given: Treatment type: Chemoembolization; Therapeutic agents: Doxorubicin Hydrochloride; Days to treatment start: 331 days; Embolic agent: Gelfoam.
   Treatment given: Treatment type: Ablation, Radiofrequency; Days to treatment start: 365 days (1.0 years); Number of cycles: 2; Lesions treated number: 1.
   Treatment given: Treatment type: Chemoembolization; Therapeutic agents: Doxorubicin Hydrochloride; Days to treatment start: 401 days (1.1 years); Embolic agent: Gelfoam.
   Treatment given: Treatment type: Ablation, Radiofrequency; Days to treatment start: 468 days (1.3 years); Number of cycles: 2; Lesions treated number: 1.
   Treatment given: Treatment type: Ablation, Radiofrequency; Days to treatment start: 594 days (1.6 years); Number of cycles: 1; Lesions treated number: 1.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Hepatocellular carcinoma, NOS), site: Liver. Age at diagnosis: 51.8 years (18,920 days); Days to diagnosis: 198 days; Prior treatment: Yes.
   Treatment given: Treatment type: Ablation or Embolization, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Organ Transplantation to Liver, for recurrent disease; Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.

Follow-up (4 entries)
- Day 198 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Local; Progression or recurrence anatomic site: Liver; Days to recurrence: 198 days.
- Days to follow up: 470 days (1.3 years); Disease response: Tumor Free.
- Days to follow up: 763 days (2.1 years); Disease response: With Tumor.
- ECOG performance status: 0.

Molecular and laboratory tests
- Creatinine 0.5 mg/dL [Blood test normal range lower: 0.7; Blood test normal range upper: 1.5].
- Platelets 211 (unit not recorded by GDC) [Blood test normal range lower: 130; Blood test normal range upper: 400].
- Prothrombin time (INR, as labelled on the TCGA clinical form) 1.1 [Blood test normal range lower: 1; Blood test normal range upper: 1].
- Total Bilirubin 0.6 mg/dL [Blood test normal range lower: 0.2; Blood test normal range upper: 1.2].
- Albumin 4 (unit not recorded on the TCGA source form) [Blood test normal range lower: 3.8; Blood test normal range upper: 5.3].
- Alpha Fetoprotein 2405 ng/mL [Blood test normal range lower: 0; Blood test normal range upper: 8].

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Alcohol Consumption / Hepatitis B Infection.
- Timepoint category: Initial Diagnosis; Weight: 69 kg; Height: 166 cm; BMI: 25.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DD-AAED-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 60 mg.
  Slide TCGA-DD-AAED-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-DD-AAED-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DD-AAED-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Histologic diagnosis: Hepatocellular Carcinoma; Definitive surgical procedure: Lobectomy; Hepatic inflammation adj tissue: Mild.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor.
- Ablations, Ablation, Ablation treatments: Ablation performed indicator: Yes.
- Ablations, Ablation, Ablation treatments, Ablation treatment 1: Ablation type: Radiofrequency Ablation; Treatment cycles count: 2; Lesions count: 1.
- Ablations, Ablation, Ablation treatments, Ablation treatment 3: Ablation type: Radiofrequency Ablation; Treatment cycles count: 1; Lesions count: 1.
- Ablations, Ablation, Embolization treatments: Embolization performed indicator: Yes.
- Ablations, Ablation, Embolization treatments, Embolization treatment 1: Embolization therapy drug name: adriamycin.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 763 days; disease-specific survival: no event (censored), 763 days; disease-free interval: event (new tumor event after initially disease-free), 198 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 198 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DD-AAED-01A-12D-A40Q-01): tumor purity 0.91, ploidy 1.87, whole-genome doublings 0.
